Somatic mutation profile of tumor specimen 0DX2D1 from CCDI case PBCPUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.7 years (605 days).
Specimen 0DX2D1: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a609956-43a1-43b3-8c7c-80ec8b7b9d76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX2CE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6973d0e-ced1-4bc4-bf75-5efb37cf98db

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 3'UTR 2, Intron 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs63749794, CM043245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- L3MBTL4 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53114204; called by muse, mutect2
- OR10G6 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV61021802; called by muse, mutect2
- SLC22A9 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV54168902; called by muse, mutect2
- SP3 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as rs775979032; called by muse, mutect2, varscan2
- INSR | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT4 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by mutect2, varscan2
- MUC19 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- NGF | c.373C>A p.H125N | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, varscan2
- SCAPER | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SCAPER | c.588T>G p.N196K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TNKS | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 44/440 reads (10%) | called by muse, mutect2
- U2AF2 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- AGBL1 | c.2250C>G p.V750= | Silent (SNP) | VAF 11/320 reads (3%) | called by muse, mutect2
- CATSPERD | c.1950G>T p.V650= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV100486926; called by muse, mutect2, varscan2
- OR4A16 | c.621C>A p.V207= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs749809790; called by muse, mutect2, varscan2
- KIF1A | c.2555+973G>A | Intron (SNP) | VAF 11/177 reads (6%) | catalogued as rs928176653; called by muse, mutect2
- NDE1 | c.*142C>A | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- PXDC1 | c.*22C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs190874440; called by mutect2, varscan2
- SCIN | chr7:12570402 G>T | 5'Flank (SNP) | VAF 36/309 reads (12%) | called by muse, mutect2
